Surgical pathology report (de-identified scan), TCGA case TCGA-CK-6747, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Harvard, specimen TCGA-CK-6747-01A (Primary Tumor).

[page 1 of 2]
Resident: [REDACTED]
Pathologist: [REDACTED]

PATHOLOGIC DIAGNOSIS:

ILEUM AND RIGHT COLON, RIGHT COLECTOMY (30.5 cm):
ADENOCARCINOMA, low grade, moderately differentiated
(4.0 cm in greatest dimension).
Tumor is located in the cecum with extension into
the wall of the ileum, forms a fungating mass, and has a pushing border.
Tumor invades through the muscularis propria and into
the subserosal adipose tissue.
The proximal and distal resection margins are negative for tumor.
Invasive tumor is 9 cm from proximal resection margin, 21.5 cm from
distal resection margin.
Lymphovascular invasion is not identified.
Extramural venous invasion is not identified.
Perineural invasion is not identified.
Peritumoral lymphoid response (including Crohn?s-like infiltrate) is
moderate.
Residual adenoma is present.
Appendix with fibrous obliteration of lumen; negative for tumor.
Diverticulosis.
Regional lymph nodes (positive:total): 0:19.
AJCC Classification [REDACTED]: T3 N0 MX.

CLINICAL DATA:

History: Not provided.
Operation: Right colectomy.
Operative Findings: Not provided.
Clinical Diagnosis: Right colon CA.

TISSUE SUBMITTED:

A. Right colon - FS rm open + return (tissue bank).

GROSS DESCRIPTION:

The specimen is received fresh in one part, labeled with the patient's name, and unit number, and "#1. Right colon", consists of a single ileocelectomy specimen including ileum (8.0 x 2.5 cm) with a proximal stapled resection margin (3.0 cm, black), colon (22.5 x 4.8 cm, distal resection margin, inked black, 4.0 cm), and appendix (5.5 cm x 0.6 cm). The specimen is opened to reveal a tan/pink ulcerating mass with raised edges (4.0 x 4.0 x 2.5 cm) which is present in the cecum and appears to abut, if not involve the ileocecal valve, and is present 9.0 cm from the proximal stapled resection margin and 21.5 cm from the distal stapled resection margin. Sectioning through the lesion demonstrates invasion into and likely through the muscularis propria. The tumor edge is located 0.4 cm from the appendix which is otherwise grossly unremarkable. The uninvolved ileal mucosa is tan/white and unremarkable. The colonic mucosa is tan/pink and contains multiple diverticula without evidence of perforation. No other lesions are identified in the specimen. Representative sections of tumor and normal colon are submitted for tissue banking.

Micro A1: Proximal and distal resection margins, 2 frags, [REDACTED]
Micro A2: Normal ileum and colon, 2 frags, [REDACTED]

[page 2 of 2]
Pathology Report

Micro A3-A7: Representative sections of tumor to deep surface, inked black, 1 frag per cassette, [REDACTED]
Micro A8: Representative section of ileocecal valve, 1 frag, [REDACTED]
Micro A9: Appendix, 3 frags, [REDACTED]
Micro A10: Representative diverticula, 1 frag, [REDACTED]
Micro A11-A17: Candidate lymph nodes, multi frags, [REDACTED]

CASE NUMBER: [REDACTED]

[REDACTED]
By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Final Diagnosis by [REDACTED]

Electronically signed on [REDACTED]

Source: NCI Genomic Data Commons file 2ec9ca9a-e6e5-40a4-a278-5012bd0733c3 (TCGA-CK-6747.B0A2F381-BE07-4BF8-A54F-0DA67B128895.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).